Somatic mutation profile of tumor specimen C3L-06020-02 (aliquot CPT0361630009) from CPTAC case C3L-06020, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.7 years (25,449 days).
Specimen C3L-06020-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3600fb-d14b-4659-b5dc-33414180cd81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06020-31 (Blood Derived Normal), aliquot CPT0361720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32e3f32e-d6bb-477f-8585-fd2e7906d651

The open-access MAF lists 659 somatic variants for this specimen: 433 protein-altering or splice-affecting, 198 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 390, Silent 198, Nonsense Mutation 28, Intron 17, Splice Site 5, Splice Region 5, 5'Flank 3, Frame Shift Del 3, RNA 3, 3'Flank 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GREB1L | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1311814599; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HAX1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 57/338 reads (17%) | catalogued as rs74315322, CM070157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 346/463 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs76687508, CM930548, COSV61018094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCSK5 | c.2771G>A p.W924* | Nonsense Mutation (SNP) | VAF 95/300 reads (32%) | hotspot (GDC flag); catalogued as COSV70451329; called by muse, varscan2
- ABCA1 | c.5266G>C p.A1756P | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV66066204; called by muse, mutect2, varscan2
- ABCB10 | c.2048G>A p.R683K | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV60621962; called by muse, varscan2
- ACACA | c.6745C>T p.R2249C | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1165714087; called by muse, varscan2
- ACSM2A | c.1377G>A p.M459I (on ENST00000219054; = p.M380I on NM_001308169.2) | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs142866996; called by muse, mutect2
- ADAMTS12 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs773706662, COSV61279076; called by muse, mutect2, varscan2
- ADCY4 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1286287758; called by muse, mutect2, varscan2
- ADCY9 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 147/450 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs770270080; called by muse, mutect2, varscan2
- ADGRV1 | c.3719G>A p.G1240E | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67996742; called by muse, mutect2, varscan2
- AHCTF1 | c.1186C>T p.R396* (on ENST00000366508; = p.R370* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 152/331 reads (46%) | catalogued as COSV58248386; called by muse, mutect2, varscan2
- AOC3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 125/456 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53828301; called by muse, varscan2
- ARHGAP28 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs377021107, COSV51637975; called by muse, mutect2, varscan2
- ARMC12 | c.311C>T p.A104V (on ENST00000373866 / NM_001286574.2; = p.A131V on NM_145028.5) | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as rs756110834; called by muse, mutect2, varscan2
- ATAD2 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54887958; called by muse, mutect2, varscan2
- ATP6V0D2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 124/322 reads (39%) | catalogued as rs759946535, COSV53415469; called by muse, mutect2, varscan2
- BPIFA1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1393655382; called by muse, mutect2, varscan2
- BUD13 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 117/449 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868374343; called by muse, mutect2, varscan2
- CACNA1I | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1389065559; called by muse, mutect2, varscan2
- CARD11 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV67796694; called by muse, mutect2, varscan2
- CCDC144A | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs1050201139; called by muse, mutect2, varscan2
- CCDC27 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 116/180 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV53901492; called by muse, varscan2
- CDH12 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 111/386 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs776746467, COSV66410447, COSV66438733; called by muse, mutect2, varscan2
- CDH20 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.383); catalogued as rs1268332328; called by muse, mutect2, varscan2
- CEP350 | c.9112G>A p.E3038K | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62608901; called by muse, mutect2, varscan2
- CFH | c.3509C>T p.S1170F | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1444285365; called by muse, mutect2, varscan2
- CHRM5 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 171/457 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67248464; called by muse, mutect2, varscan2
- CNTNAP2 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs866697251, COSV62225965, COSV62243617; called by muse, mutect2, varscan2
- COL4A5 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 124/189 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM050038; called by muse, mutect2, varscan2
- CPEB3 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV56456400; called by muse, varscan2
- CPS1 | c.3164C>T p.S1055L | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868098566, COSV99243225; called by muse, varscan2
- CSMD3 | c.9973G>A p.G3325R (on ENST00000297405 / NM_001363185.1; = p.G3156R on NM_052900.3) | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482852766, COSV52139725; called by muse, mutect2, varscan2
- CSMD3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1444297700, COSV52103573; called by muse, mutect2, varscan2
- CUL2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66080198; called by muse, mutect2, varscan2
- CYP3A4 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1442597092; called by muse, mutect2, varscan2
- CYP4F11 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 149/551 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs144938795; called by muse, mutect2, varscan2
- DCBLD1 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1315925529; called by muse, mutect2, varscan2
- DCLK2 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs772172177, COSV56204210, COSV56206882; called by muse, varscan2
- DDX27 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 88/278 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs267605977; called by muse, mutect2, varscan2
- DENND3 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs1368369994; called by muse, mutect2
- DNAH6 | c.6287G>A p.G2096E | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52861602; called by muse, mutect2, varscan2
- DNAH9 | c.6406C>T p.Q2136* | Nonsense Mutation (SNP) | VAF 60/220 reads (27%) | catalogued as rs1245110367; called by muse, mutect2, varscan2
- DPPA3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.049); catalogued as COSV61502894; called by muse, mutect2, varscan2
- DPYS | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 109/364 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100679823; called by muse, mutect2, varscan2
- DSC3 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV100844612; called by muse, mutect2, varscan2
- DSCAM | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs747704315, COSV68025455; called by muse, mutect2, varscan2
- DSPP | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs1355843745, COSV56810235; called by muse, mutect2, varscan2
- EDDM3B | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs758148541, COSV58747021; called by muse, mutect2, varscan2
- EFR3A | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as COSV99602243; called by muse, mutect2, varscan2
- EHMT2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 254/522 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); catalogued as COSV64997945; called by muse, varscan2
- EIF4G3 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 339/431 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1236563032; called by muse, mutect2, varscan2
- ELMOD1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV56195232; called by muse, mutect2, varscan2
- ENTHD1 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 138/384 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1214498229; called by muse, mutect2, varscan2
- EPAS1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as rs1449817007; called by muse, mutect2, varscan2
- EPB41L2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 120/391 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100440418; called by muse, varscan2
- EVPL | c.4726C>T p.R1576W | Missense Mutation (SNP) | VAF 181/506 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs750859177; called by muse, varscan2
- F13B | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66373340, COSV66374568; called by muse, varscan2
- FAM13C | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53249102; called by muse, mutect2, varscan2
- FAM155A | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65589363; called by muse, mutect2, varscan2
- FAT4 | c.14932G>A p.E4978K | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV58681829; called by muse, mutect2, varscan2
- FBN2 | c.4208G>A p.G1403D | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750327890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBRSL1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 150/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208490204; called by muse, mutect2, varscan2
- FGB | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV57419912; called by muse, mutect2, varscan2
- FLG | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 245/483 reads (51%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.528); catalogued as rs372997287; called by muse, mutect2, varscan2
- FMR1NB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63272717; called by muse, mutect2, varscan2
- FOS | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 302/589 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1265119657; called by muse, mutect2, varscan2
- FOXJ1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 150/422 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764302833, COSV53943056; called by muse, mutect2, varscan2
- FREM3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 127/438 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1243007113; called by muse, mutect2, varscan2
- GABRG2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868720581, COSV62721015; called by muse, mutect2, varscan2
- GABRR3 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 90/269 reads (33%) | catalogued as rs1162181938; called by muse, mutect2, varscan2
- GALNT18 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766330240, COSV57158522; called by muse, mutect2, varscan2
- GIMAP4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 113/491 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1380851038; called by muse, mutect2, varscan2
- GNAS | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as rs1338347974, COSV58346166; called by muse, mutect2, varscan2
- GPR179 | c.6494G>A p.G2165E (on ENST00000621958; = p.G2164E on NM_001004334.4) | Missense Mutation (SNP) | VAF 136/531 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs1249735936; called by muse, mutect2, varscan2
- GRID2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56170467, COSV99936908; called by muse, mutect2, varscan2
- GRK7 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53822219; called by muse, mutect2, varscan2
- GRM2 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329180037, COSV56585646; called by muse, mutect2, varscan2
- HDGFL2 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 249/536 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56683864; called by muse, varscan2
- HEPACAM | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.905); catalogued as rs776436789; called by muse, mutect2, varscan2
- HHIPL1 | c.1864_1889del p.T622Hfs*187 | Frame Shift Del (DEL) | VAF 90/293 reads (31%) | catalogued as rs1355052177; called by mutect2, varscan2
- IGHA1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 146/1044 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774279646; called by muse, mutect2, varscan2
- IGHA2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1555452761; called by muse, mutect2, varscan2
- INO80 | c.2848C>T p.L950F | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs1361967725; called by muse, varscan2
- INPP1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100487214; called by muse, varscan2
- ITGA8 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1276881903, COSV65227763; called by muse, mutect2, varscan2
- ITGA9 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs376199202, COSV53238804; called by muse, mutect2, varscan2
- KDM5B | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV52508690; called by muse, mutect2, varscan2
- KIAA0319 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100985129; called by muse, mutect2, varscan2
- KIAA1549 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 130/539 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV54328125; called by muse, mutect2, varscan2
- KIF21B | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1323330319; called by muse, mutect2, varscan2
- KIF9 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773610436, COSV55520707, COSV55524288; called by muse, mutect2, varscan2
- KPNA2 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57857120; called by muse, mutect2
- KPNA5 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1016200852, COSV62651747; called by muse, mutect2, varscan2
- KRT14 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868637793; called by muse, mutect2, varscan2
- KRT2 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 137/456 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as COSV59009420; called by muse, mutect2, varscan2
- KRT39 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100842283; called by muse, mutect2, varscan2
- KRTAP10-4 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 198/1382 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.813); catalogued as rs1357735796; called by muse, mutect2
- KRTAP4-4 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 157/576 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs763088003; called by muse, mutect2, varscan2
- LAMA2 | c.6062G>A p.G2021E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101370878; called by muse, mutect2, varscan2
- LILRA4 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 140/772 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201646669; called by muse, varscan2
- LILRB2 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 168/537 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370060797; called by muse, mutect2, varscan2
- LMF2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370076519; called by muse, mutect2, varscan2
- LONRF3 | c.1339C>T p.Q447* (on ENST00000371628 / NM_001031855.3; = p.Q406* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 138/223 reads (62%) | catalogued as rs888998754; called by muse, mutect2, varscan2
- LRP1B | c.13058G>A p.G4353E | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV67196440; called by muse, mutect2, varscan2
- LRRC3B | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 143/435 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868235124; called by muse, mutect2, varscan2
- LRRTM3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 137/415 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1364456221, COSV63663217; called by muse, mutect2, varscan2
- LTBP2 | c.3068G>A p.G1023E | Missense Mutation (SNP) | VAF 93/384 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264330615; called by muse, mutect2, varscan2
- LVRN | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.09); catalogued as COSV63496072, COSV63497871; called by muse, mutect2, varscan2
- LYPD4 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs200441266; called by muse, mutect2, varscan2
- MAPK8IP1 | c.2108G>T p.C703F | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751413728; called by muse, mutect2, varscan2
- MMP3 | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55405092; called by muse, mutect2, varscan2
- MORC1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868626562, COSV99226998; called by muse, mutect2, varscan2
- MPZL1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 89/392 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as rs368816230; called by muse, mutect2, varscan2
- MUC16 | c.26111C>T p.S8704F | Missense Mutation (SNP) | VAF 112/561 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.631); catalogued as rs866103352, COSV67486445; called by muse, mutect2, varscan2
- MUC16 | c.10439G>A p.G3480E | Missense Mutation (SNP) | VAF 223/490 reads (46%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV67458733; called by muse, mutect2, varscan2
- MX2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 60/171 reads (35%) | catalogued as rs751048457, COSV58095396; called by muse, mutect2, varscan2
- MYO6 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs377681616; called by muse, mutect2, varscan2
- MYOC | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 139/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759114694, CM092549, COSV50676546; called by muse, varscan2
- NAALADL2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV69156515; called by muse, mutect2, varscan2
- NBEA | c.7472C>T p.S2491F | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080909; called by muse, mutect2, varscan2
- NLRP14 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV55073136; called by muse, mutect2, varscan2
- NPNT | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 142/497 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as rs761569898, COSV59752623; called by muse, mutect2, varscan2
- NPR2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV61311378; called by muse, varscan2
- OR13C3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 142/443 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66165698; called by muse, mutect2, varscan2
- OR4C46 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750730898, COSV60218447; called by muse, mutect2, varscan2
- OR4C46 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1233021940, COSV60219138; called by muse, mutect2, varscan2
- OR9Q2 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 94/317 reads (30%) | catalogued as rs757826869, COSV61111553; called by muse, mutect2, varscan2
- OTOA | c.1253C>T p.S418F (on ENST00000286149; = p.S404F on NM_144672.4) | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs868568322; called by muse, mutect2, varscan2
- OXGR1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100036901; called by muse, mutect2, varscan2
- OXSM | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1372815916, COSV99772110; called by muse, mutect2, varscan2
- PALD1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1460279883; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 112/538 reads (21%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PCDH15 | c.2869G>A p.G957R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57265314, COSV57360873; called by muse, mutect2, varscan2
- PCDH18 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1560724981; called by muse, mutect2, varscan2
- PCDHA12 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV56513293; called by muse, mutect2, varscan2
- PCDHA4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV100793545; called by muse, mutect2, varscan2
- PCDHB14 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as rs782757081; called by muse, mutect2, varscan2
- PCDHB2 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 195/675 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.13); catalogued as rs1554271593, COSV50564882; called by muse, mutect2, varscan2
- PCDHB4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52025415; called by muse, mutect2, varscan2
- PCNX2 | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV50904023; called by muse, mutect2, varscan2
- PDE11A | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV61775125; called by muse, mutect2, varscan2
- PDLIM4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 125/461 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.878); catalogued as COSV53803203; called by muse, mutect2, varscan2
- PITPNM1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 182/590 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1195337889; called by muse, mutect2, varscan2
- PKD1 | c.5948G>A p.G1983D | Missense Mutation (SNP) | VAF 148/476 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1223013836; called by muse, mutect2, varscan2
- PKHD1 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61876113; called by muse, varscan2
- PKHD1L1 | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771453720, COSV65747923; called by muse, mutect2, varscan2
- PLCE1 | c.5906G>A p.R1969Q | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs1323373118, CM156519, COSV53347495; called by muse, mutect2, varscan2
- PNLIP | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs781625860, COSV65040734; called by muse, varscan2
- PPAN-P2RY11 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1396958628, COSV99460619; called by muse, mutect2, varscan2
- PPFIA1 | c.2960G>A p.C987Y | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs749280540; called by muse, mutect2, varscan2
- PREX2 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs371787029, COSV55755479; called by muse, mutect2, varscan2
- PRKCH | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 230/453 reads (51%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.472); catalogued as COSV60648024; called by muse, mutect2, varscan2
- PRKCQ | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV54117499; called by muse, mutect2, varscan2
- PRKG1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs766091359, COSV64777133; called by muse, mutect2, varscan2
- PTCH1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59467588; called by muse, mutect2, varscan2
- PTPRB | c.2894G>A p.R965K | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1404029902; called by muse, mutect2, varscan2
- PTPRM | c.3491C>T p.A1164V | Missense Mutation (SNP) | VAF 120/356 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV59857860; called by muse, mutect2, varscan2
- PTPRQ | c.6551G>A p.R2184K (on ENST00000616559; = p.R2151K on NM_001145026.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1296476971; called by muse, mutect2
- PTPRQ | c.6552G>A p.R2184= (on ENST00000616559; = p.R2151= on NM_001145026.2) | Splice Region (SNP) | VAF 10/58 reads (17%) | catalogued as rs1347008394, COSV57036706, COSV57038959; called by muse, mutect2
- PXDNL | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as COSV100686011; called by muse, varscan2
- RANBP17 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as COSV66652727; called by muse, mutect2, varscan2
- RCOR1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51767328; called by muse, mutect2, varscan2
- RHOXF2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 183/631 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs373969876, COSV65047954; called by muse, mutect2, varscan2
- RP1 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV55112056; called by muse, mutect2, varscan2
- RPH3A | c.1408G>A p.D470N (on ENST00000389385 / NM_001143854.2; = p.D466N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/331 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs771156884, COSV66990434; called by muse, mutect2, varscan2
- RUNX1T1 | c.1315G>A p.G439R (on ENST00000265814 / NM_001198628.1; = p.G412R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99756196; called by muse, mutect2, varscan2
- SALL4 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 180/496 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53855960; called by muse, mutect2, varscan2
- SEMA3E | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 90/400 reads (23%) | catalogued as rs377657646, COSV57093548; called by muse, mutect2, varscan2
- SHARPIN | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs762440714; called by muse, mutect2, varscan2
- SIRPD | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs750394181; called by muse, mutect2, varscan2
- SLAMF8 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 138/591 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV99223152; called by muse, mutect2, varscan2
- SLC12A8 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs201194975, COSV58867992; called by muse, mutect2
- SLC13A2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100120066, COSV58999097; called by muse, mutect2, varscan2
- SLC8A1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 102/352 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1057186496; called by muse, mutect2, varscan2
- SLIT2 | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 71/238 reads (30%) | catalogued as COSV56564709; called by muse, mutect2, varscan2
- SLIT3 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 134/387 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100265328; called by muse, mutect2, varscan2
- SMOC1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 207/437 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62761456; called by muse, mutect2, varscan2
- SP7 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 160/482 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1565789995; called by muse, mutect2, varscan2
- SPART | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 118/405 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV62085746; called by muse, mutect2, varscan2
- SPATA18 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54646857; called by muse, mutect2, varscan2
- SPEG | c.7075G>A p.E2359K | Missense Mutation (SNP) | VAF 126/468 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs751168046; called by muse, mutect2, varscan2
- SPTBN2 | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 117/362 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs148878156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAB2 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66347715; called by muse, mutect2, varscan2
- STXBP5L | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56507809; called by muse, mutect2, varscan2
- SUGP2 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV58260320; called by muse, mutect2, varscan2
- SUSD4 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV59557149, COSV59557241; called by muse, mutect2, varscan2
- SYT4 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 82/255 reads (32%) | catalogued as COSV99673542; called by muse, mutect2, varscan2
- TG | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 140/440 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV55064783; called by muse, mutect2, varscan2
- TINAG | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 118/328 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.114); catalogued as rs75755871; called by muse, mutect2, varscan2
- TM7SF3 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.825); catalogued as rs376448339, COSV58003221; called by muse, mutect2, varscan2
- TMEM132D | c.2729C>T p.S910F | Missense Mutation (SNP) | VAF 139/400 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as COSV67162705; called by muse, mutect2, varscan2
- TMEM187 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 187/302 reads (62%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); catalogued as rs782287239; called by muse, mutect2, varscan2
- TMPRSS3 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs377604843; called by muse, mutect2, varscan2
- TNRC18 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 146/615 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs902811044, COSV68164285; called by muse, mutect2, varscan2
- TPH1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51457093; called by muse, mutect2, varscan2
- TRAPPC2L | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 113/393 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142196121; called by muse, mutect2, varscan2
- TREML2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 19/599 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1351538970; called by muse, mutect2
- TRIM54 | c.961G>A p.E321K (on ENST00000380075 / NM_187841.3; = p.E363K on NM_032546.4) | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs868422808, COSV51991055; called by muse, varscan2
- TTN | c.22264C>T p.R7422* (on ENST00000591111; = p.R6495* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/259 reads (31%) | catalogued as rs372250586, COSV59981639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXLNB | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs866252511, COSV64443021; called by muse, mutect2, varscan2
- UGT2B28 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100159004; called by muse, mutect2, varscan2
- USP54 | c.3764G>A p.G1255E | Missense Mutation (SNP) | VAF 111/414 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV60444796; called by muse, mutect2, varscan2
- USP9X | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 98/184 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100199526; called by muse, mutect2, varscan2
- VIP | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV65888885; called by muse, mutect2, varscan2
- WT1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.138); catalogued as rs144788858; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- XIRP2 | c.9346G>A p.D3116N (on ENST00000628543; = p.D3291N on NM_152381.6) | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs772297189, COSV54702305; called by muse, mutect2, varscan2
- ZFHX4 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 122/444 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1333886732, COSV51488119; called by muse, mutect2, varscan2
- ZMYND15 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.938); catalogued as COSV99351328; called by muse, mutect2, varscan2
- ZNF439 | c.1152C>G p.C384W | Missense Mutation (SNP) | VAF 98/489 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58308370; called by muse, mutect2, varscan2
- ZNF541 | c.3159A>G p.P1053= | Splice Region (SNP) | VAF 49/233 reads (21%) | catalogued as rs761212973; called by muse, mutect2, varscan2
- ZNF71 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 134/399 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1568509734; called by muse, varscan2
- ZNF750 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 146/467 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs757683345; called by muse, mutect2, varscan2
- ZP2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs747490006; called by muse, mutect2, varscan2
- ZP2 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs535760240, COSV54816524; called by muse, mutect2, varscan2
- ZW10 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV52314955; called by muse, mutect2, varscan2
- AATK | c.2971C>T p.P991S (on ENST00000326724 / NM_001080395.3; = p.P888S on NM_004920.2) | Missense Mutation (SNP) | VAF 152/474 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- ABCB1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCC3 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 168/541 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACADSB | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2B | c.1377G>A p.M459I | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ADAM7 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRF4 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 104/371 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD34C | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ARHGEF1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- BCL10 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 150/299 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BFSP2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- BSN | c.8290G>A p.D2764N | Missense Mutation (SNP) | VAF 144/432 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf71 | c.4304C>T p.S1435F | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf78 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- C1orf116 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 141/651 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf94 | c.887C>G p.P296R (on ENST00000488417 / NM_001134734.2; = p.P106R on NM_032884.5) | Missense Mutation (SNP) | VAF 426/583 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- C5orf52 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 131/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CACNA1I | c.6319G>A p.D2107N | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CAPN13 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CARD10 | c.2623G>A p.V875M | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- CBLC | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 177/511 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CBLC | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC14 | c.230+1G>T p.X77_splice (on ENST00000488653; = p.X29_splice on NM_022757.5) | Splice Site (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- CCDC61 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH17 | c.285+1G>A p.X95_splice | Splice Site (SNP) | VAF 74/207 reads (36%) | called by muse, mutect2, varscan2
- CEACAM16 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 120/364 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP112 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 87/290 reads (30%) | called by muse, mutect2, varscan2
- CEP68 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CIT | c.5978C>T p.S1993F | Missense Mutation (SNP) | VAF 154/504 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- CMKLR1 | c.1018G>A p.E340K (on ENST00000312143 / NM_001142344.2; = p.E338K on NM_004072.3) | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CNGB3 | c.2312G>A p.R771K | Missense Mutation (SNP) | VAF 134/466 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- COL20A1 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 133/458 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- COL28A1 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL4A3 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 133/413 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- COLEC12 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CPB1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPS1 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPXCR1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 166/256 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP11A1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- CYP2C8 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2E1 | c.1265A>C p.K422T | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- CYP2J2 | c.995A>G p.E332G | Missense Mutation (SNP) | VAF 128/254 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- DAPK1 | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 147/422 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, varscan2
- DCDC2 | c.1326+1G>A p.X442_splice | Splice Site (SNP) | VAF 115/256 reads (45%) | called by muse, mutect2, varscan2
- DCLRE1A | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by mutect2, varscan2
- DNAH14 | c.5242G>A p.E1748K (on ENST00000445597; = p.E2153K on NM_001367479.1) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH3 | c.4710G>A p.M1570I | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.3917G>T p.W1306L | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DNAH6 | c.8086C>T p.L2696F | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH8 | c.7733G>A p.G2578D | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.5747G>A p.G1916D | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 244/547 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK3 | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- DRD2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSCAM | c.2527G>A p.G843R | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EDN3 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ELAVL4 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 246/360 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ENPP4 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ERICH3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 125/165 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBLN5 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 76/379 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FBXO21 | c.1508A>T p.Y503F (on ENST00000330622 / NM_033624.3; = p.Y496F on NM_015002.3) | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FIGNL2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 169/568 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FILIP1L | c.1551A>T p.K517N (on ENST00000354552 / NM_182909.3; = p.K277N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- FLT3 | c.1922T>C p.V641A | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCKR | c.1631T>A p.F544Y | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GEMIN4 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 148/461 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHDC | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT tolerated (0.6); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLIS1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 527/753 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR108 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- GRN | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 100/289 reads (35%) | called by muse, mutect2, varscan2
- GSDME | c.1333T>C p.F445L | Missense Mutation (SNP) | VAF 132/519 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- HDAC4 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- HEATR3 | c.2020G>T p.V674F | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- HECTD4 | c.8130G>A p.M2710I | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- HEPH | c.1706G>A p.G569D (on ENST00000343002; = p.G302D on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/202 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- HEXIM2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, varscan2
- IGSF11 | c.1042C>T p.H348Y (on ENST00000393775 / NM_001015887.3; = p.H347Y on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.04); called by muse, varscan2
- IPO11 | c.2470C>T p.L824F | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IQUB | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 62/317 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ISL1 | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ITGA5 | c.3025G>A p.G1009S | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA8 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ITGA9 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, varscan2
- ITPR2 | c.6837T>A p.F2279L | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNMA1 | c.2689C>T p.P897S (on ENST00000286628 / NM_001161352.2; = p.P839S on NM_002247.4) | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNS2 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 133/430 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIFC1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 210/799 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KRT34 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- KRT5 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- L3MBTL4 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 107/351 reads (30%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1058G>A p.W353* | Nonsense Mutation (SNP) | VAF 106/352 reads (30%) | called by muse, mutect2, varscan2
- LAP3 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- LHX8 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LINC01505 | n.475G>A | Splice Region (SNP) | VAF 65/230 reads (28%) | called by muse, varscan2
- LOXL4 | c.1892C>A p.S631Y | Missense Mutation (SNP) | VAF 111/344 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRFN5 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 134/543 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LRRC58 | c.994T>C p.S332P | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LTBP4 | c.4255G>A p.G1419R (on ENST00000308370 / NM_001042544.1; = p.G1382R on NM_003573.2) | Missense Mutation (SNP) | VAF 164/482 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6G6E | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 104/468 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, varscan2
- LYPD8 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAGEA3 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 144/253 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MAGEB5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 136/225 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MAP3K9 | c.2761C>T p.L921F (on ENST00000554752 / NM_001284230.1; = p.L935F on NM_033141.4) | Missense Mutation (SNP) | VAF 235/580 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- METTL21A | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- METTL9 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD4A | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD6L | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 136/425 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MGAM2 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLLT3 | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MRC1 | c.2543G>A p.W848* | Nonsense Mutation (SNP) | VAF 59/238 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.11312C>A p.P3771Q | Missense Mutation (SNP) | VAF 241/499 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- MYOCD | c.234del p.N79Ifs*19 | Frame Shift Del (DEL) | VAF 61/266 reads (23%) | called by mutect2, pindel, varscan2
- NCR2 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 74/240 reads (31%) | called by muse, mutect2, varscan2
- NECAB2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFATC3 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 131/358 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NFRKB | c.2023G>T p.A675S (on ENST00000446488 / NM_001143835.2; = p.A700S on NM_006165.3) | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NIPBL | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME9 | c.773G>A p.R258K (on ENST00000333911 / NM_001349024.2; = p.R197K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NOM1 | c.929T>A p.F310Y | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NOS3 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 139/295 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- NPNT | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 140/495 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 88/448 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.066); called by muse, varscan2
- NPR2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 133/356 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NPY1R | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 109/382 reads (29%) | called by muse, mutect2, varscan2
- OR10G7 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 112/776 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR10G9 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52B2 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8K1 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 15/469 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2
- OR9K2 | c.977A>C p.K326T (on ENST00000305377; = p.K304T on NM_001005243.1) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- P2RY2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 136/476 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACS2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 122/451 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPLN | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 115/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PARP14 | c.3003_3015del p.S1002Efs*14 | Frame Shift Del (DEL) | VAF 103/378 reads (27%) | called by mutect2, pindel, varscan2
- PCDH1 | c.3140C>T p.P1047L | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, varscan2
- PCDHA11 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 151/493 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PCDHA6 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 161/541 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHGB1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 136/454 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PCED1B | c.338A>T p.E113V | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, varscan2
- PCNX3 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 130/435 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PER1 | c.1948A>G p.K650E | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PGC | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PIEZO2 | c.5992G>A p.D1998N | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIGN | c.2793G>T p.M931I | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP5K1B | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PKN1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 155/664 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PNLIP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PSEN1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 97/520 reads (19%) | called by muse, mutect2, varscan2
- PTPRB | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RALGAPA1 | c.6077C>T p.P2026L | Missense Mutation (SNP) | VAF 125/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RASA3 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 155/259 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- RBMXL2 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RGPD4 | c.3634G>A p.D1212N | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- RHOF | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.519); called by muse, varscan2
- RICTOR | c.3835C>T p.L1279F | Missense Mutation (SNP) | VAF 99/360 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- RNF216 | c.1571T>G p.F524C (on ENST00000425013 / NM_207116.3; = p.F581C on NM_207111.4) | Missense Mutation (SNP) | VAF 107/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RPP30 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, varscan2
- RSPH6A | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 156/494 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, varscan2
- RTP2 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SGF29 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 136/446 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SI | c.4016C>T p.P1339L | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SKA3 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | called by muse, mutect2, varscan2
- SKI | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 351/529 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A1 | c.2704T>A p.F902I | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SLC25A20 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A5 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 169/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SLC28A1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 101/400 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC34A1 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 137/446 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35B4 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- SLC6A12 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SORL1 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SP100 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SPATA31A1 | c.2054A>C p.D685A | Missense Mutation (SNP) | VAF 148/548 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPATA31A3 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); called by mutect2, varscan2
- SPATA7 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 197/449 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPEG | c.6305C>T p.P2102L | Missense Mutation (SNP) | VAF 182/585 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTA1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 111/475 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SRCIN1 | c.2761G>A p.G921R (on ENST00000621492; = p.G887R on NM_025248.3) | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SRL | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAB2 | c.708C>T p.D236= | Splice Region (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- TARM1 | c.835G>A p.E279K (on ENST00000616041 / NM_001330650.1; = p.E271K on NM_001135686.3) | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TAS1R2 | c.1672T>A p.F558I | Missense Mutation (SNP) | VAF 225/380 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TAS1R2 | c.1466C>G p.T489R | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TENM3 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 105/305 reads (34%) | called by muse, mutect2, varscan2
- TET3 | c.142_143dup p.D49Efs*45 | Frame Shift Ins (INS) | VAF 114/434 reads (26%) | called by pindel, varscan2
- TEX15 | c.39G>C p.Q13H (on ENST00000638951; = p.Q9H on NM_001350162.2) | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.56); called by muse, mutect2, varscan2
- THSD7B | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- TIMM44 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TINAG | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TLCD3B | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM30A | c.346-17_364del p.X116_splice | Splice Site (DEL) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 170/546 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TNNT3 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, varscan2
- TPP2 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPC6 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPM6 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 173/550 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TTN | c.91096G>A p.E30366K (on ENST00000591111; = p.E22942K on NM_003319.4) | Missense Mutation (SNP) | VAF 78/224 reads (35%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.69430C>T p.H23144Y (on ENST00000591111; = p.H15720Y on NM_003319.4) | Missense Mutation (SNP) | VAF 114/379 reads (30%) | PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TUBA8 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNDC16 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TXNDC2 | c.628C>T p.P210S (on ENST00000306084 / NM_001098529.2; = p.P143S on NM_032243.6) | Missense Mutation (SNP) | VAF 178/580 reads (31%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- UBASH3B | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, varscan2
- UROC1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP54 | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- VN1R2 | c.1100T>A p.L367H | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPO1 | c.2986C>T p.L996F | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- XPOT | c.2758C>T p.Q920* | Nonsense Mutation (SNP) | VAF 76/228 reads (33%) | called by muse, mutect2, varscan2
- ZBTB10 | c.2128T>G p.W710G (on ENST00000430430; = p.W686G on NM_023929.4) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZDHHC2 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFHX4 | c.7333C>T p.Q2445* | Nonsense Mutation (SNP) | VAF 160/512 reads (31%) | called by muse, mutect2, varscan2
- ZNF334 | c.150G>A p.G50= | Splice Region (SNP) | VAF 59/213 reads (28%) | called by muse, mutect2, varscan2
- ZNF717 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 110/434 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZNF773 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 137/445 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF836 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACACA | c.6744C>T p.S2248= | Silent (SNP) | VAF 82/284 reads (29%) | called by muse, varscan2
- ACADVL | c.534G>A p.L178= | Silent (SNP) | VAF 127/393 reads (32%) | called by muse, mutect2, varscan2
- ACVR2B | c.450C>T p.S150= | Silent (SNP) | VAF 142/505 reads (28%) | catalogued as rs1425273847; called by muse, mutect2, varscan2
- ADAM28 | c.1368C>T p.C456= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- ADCY5 | c.2766C>T p.S922= | Silent (SNP) | VAF 130/386 reads (34%) | catalogued as rs1158175611; called by muse, mutect2, varscan2
- ADCY5 | c.1545C>T p.I515= | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs764940624; called by muse, mutect2, varscan2
- ADGRF2 | c.363A>G p.Q121= (on ENST00000296862 / NM_001368115.2; = p.Q53= on NM_153839.7) | Silent (SNP) | VAF 96/293 reads (33%) | catalogued as rs368305100; called by muse, mutect2, varscan2
- AKAP13 | c.1627C>T p.L543= | Silent (SNP) | VAF 145/532 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.5325C>T p.A1775= | Silent (SNP) | VAF 95/372 reads (26%) | called by muse, mutect2, varscan2
- ASPM | c.4410C>T p.I1470= | Silent (SNP) | VAF 88/194 reads (45%) | called by muse, mutect2, varscan2
- ATP4B | c.15G>A p.Q5= | Silent (SNP) | VAF 213/364 reads (59%) | catalogued as rs1161567816; called by muse, mutect2, varscan2
- BAAT | c.1140G>A p.L380= | Silent (SNP) | VAF 148/499 reads (30%) | catalogued as COSV52287911; called by muse, mutect2, varscan2
- BMP2 | c.663C>T p.H221= | Silent (SNP) | VAF 117/336 reads (35%) | catalogued as rs757394512, COSV66579553; called by muse, mutect2, varscan2
- C1orf105 | c.360C>T p.P120= | Silent (SNP) | VAF 77/325 reads (24%) | catalogued as COSV62959332; called by muse, mutect2, varscan2
- CACNA1I | c.6318G>A p.S2106= | Silent (SNP) | VAF 118/398 reads (30%) | called by muse, mutect2, varscan2
- CACNG3 | c.789G>A p.S263= | Silent (SNP) | VAF 156/485 reads (32%) | catalogued as rs749942057, COSV50070361; called by muse, mutect2, varscan2
- CCL25 | c.16C>T p.L6= | Silent (SNP) | VAF 231/512 reads (45%) | catalogued as rs1435516503; called by muse, mutect2, varscan2
- CCNP | c.117T>G p.P39= | Silent (SNP) | VAF 170/524 reads (32%) | called by muse, varscan2
- CDH9 | c.30C>T p.F10= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as rs933840296; called by muse, mutect2, varscan2
- CFHR4 | c.777A>G p.S259= (on ENST00000367416 / NM_001201551.2; = p.S260= on NM_001201550.3) | Silent (SNP) | VAF 79/267 reads (30%) | catalogued as rs1352525399; called by muse, mutect2, varscan2
- CHIA | c.1143C>T p.S381= (on ENST00000343320; = p.S273= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 89/459 reads (19%) | catalogued as rs368203516; called by muse, mutect2, varscan2
- CILP | c.1704C>T p.I568= | Silent (SNP) | VAF 151/453 reads (33%) | called by muse, mutect2, varscan2
- CLEC5A | c.252C>T p.F84= | Silent (SNP) | VAF 58/340 reads (17%) | catalogued as COSV101407788; called by mutect2, varscan2
- CLK1 | c.753C>T p.F251= | Silent (SNP) | VAF 60/235 reads (26%) | catalogued as COSV58433428; called by muse, mutect2, varscan2
- CLPX | c.1884A>G p.A628= | Silent (SNP) | VAF 64/271 reads (24%) | called by muse, mutect2, varscan2
- CMA1 | c.18C>T p.L6= | Silent (SNP) | VAF 114/472 reads (24%) | called by muse, mutect2, varscan2
- CNN1 | c.456C>T p.F152= | Silent (SNP) | VAF 228/482 reads (47%) | catalogued as rs762813878, COSV52955141; called by muse, mutect2, varscan2
- COL4A3 | c.2721G>A p.G907= | Silent (SNP) | VAF 108/352 reads (31%) | called by muse, mutect2, varscan2
- CPNE4 | c.891G>A p.L297= | Silent (SNP) | VAF 84/270 reads (31%) | catalogued as rs1420112663; called by muse, mutect2, varscan2
- CPXCR1 | c.675G>A p.G225= | Silent (SNP) | VAF 100/169 reads (59%) | catalogued as rs753992738, COSV52161956; called by muse, mutect2, varscan2
- CRIM1 | c.2397G>A p.L799= | Silent (SNP) | VAF 87/297 reads (29%) | called by muse, mutect2, varscan2
- CYP1A2 | c.246C>T p.S82= | Silent (SNP) | VAF 290/657 reads (44%) | catalogued as rs376107702; called by muse, mutect2, varscan2
- CYP4F2 | c.1548G>A p.V516= | Silent (SNP) | VAF 84/497 reads (17%) | catalogued as rs1441605299; called by muse, mutect2, varscan2
- DCLRE1B | c.1026G>A p.R342= | Silent (SNP) | VAF 105/524 reads (20%) | called by muse, mutect2, varscan2
- DDX24 | c.660C>T p.A220= | Silent (SNP) | VAF 144/575 reads (25%) | called by muse, mutect2, varscan2
- DGKH | c.1353C>T p.T451= | Silent (SNP) | VAF 66/199 reads (33%) | catalogued as rs541673467, COSV99819447; called by muse, mutect2, varscan2
- DLEC1 | c.2007C>T p.I669= | Silent (SNP) | VAF 111/397 reads (28%) | called by muse, mutect2, varscan2
- DNAH7 | c.6237C>T p.S2079= | Silent (SNP) | VAF 99/296 reads (33%) | catalogued as rs748954474, COSV100416396; called by muse, mutect2, varscan2
- DRC7 | c.462C>T p.S154= | Silent (SNP) | VAF 83/248 reads (33%) | catalogued as rs369357794; called by muse, mutect2, varscan2
- DSC2 | c.1284G>A p.K428= | Silent (SNP) | VAF 76/208 reads (37%) | called by muse, mutect2, varscan2
- EFCAB12 | c.1125C>T p.T375= | Silent (SNP) | VAF 157/449 reads (35%) | catalogued as rs1448846074; called by muse, mutect2, varscan2
- EIF2B2 | c.324C>T p.S108= | Silent (SNP) | VAF 180/409 reads (44%) | called by muse, varscan2
- FAM47A | c.591C>T p.S197= | Silent (SNP) | VAF 137/205 reads (67%) | catalogued as COSV100649789; called by muse, mutect2, varscan2
- FAM81B | c.837G>A p.S279= | Silent (SNP) | VAF 71/272 reads (26%) | catalogued as rs996500686; called by muse, mutect2, varscan2
- FBLN5 | c.147C>T p.I49= | Silent (SNP) | VAF 76/376 reads (20%) | called by muse, mutect2, varscan2
- FBRSL1 | c.1683C>T p.A561= | Silent (SNP) | VAF 103/361 reads (29%) | called by muse, mutect2, varscan2
- FBRSL1 | c.2373C>T p.P791= | Silent (SNP) | VAF 150/466 reads (32%) | called by muse, mutect2, varscan2
- FKBP6 | c.981T>C p.S327= | Silent (SNP) | VAF 165/349 reads (47%) | called by muse, mutect2, varscan2
- FREM2 | c.7851C>T p.S2617= | Silent (SNP) | VAF 135/408 reads (33%) | called by muse, mutect2, varscan2
- FRK | c.870C>T p.I290= | Silent (SNP) | VAF 65/249 reads (26%) | catalogued as COSV73383809; called by muse, mutect2, varscan2
- GABRG1 | c.603C>T p.S201= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1446211119, COSV54950739, COSV54956699; called by muse, mutect2, varscan2
- GALNT10 | c.1347C>T p.F449= | Silent (SNP) | VAF 95/300 reads (32%) | called by muse, mutect2, varscan2
- GML | c.282C>T p.F94= | Silent (SNP) | VAF 96/310 reads (31%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1089G>A p.K363= | Silent (SNP) | VAF 94/1062 reads (9%) | called by muse, varscan2
- GPR179 | c.6495G>A p.G2165= (on ENST00000621958; = p.G2164= on NM_001004334.4) | Silent (SNP) | VAF 133/532 reads (25%) | called by muse, mutect2, varscan2
- GPR37L1 | c.357C>T p.P119= | Silent (SNP) | VAF 391/780 reads (50%) | called by muse, mutect2, varscan2
- GUCY2D | c.1111A>C p.R371= | Silent (SNP) | VAF 151/541 reads (28%) | called by muse, mutect2, varscan2
- H2BC10 | c.123C>T p.Y41= | Silent (SNP) | VAF 268/606 reads (44%) | catalogued as rs771704074, COSV59953831; called by muse, varscan2
- HAX1 | c.567C>T p.S189= | Silent (SNP) | VAF 58/337 reads (17%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.972C>T p.G324= | Silent (SNP) | VAF 32/251 reads (13%) | called by muse, mutect2, varscan2
- HYDIN | c.10806C>T p.I3602= | Silent (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- IGHG3 | c.730C>T p.L244= | Silent (SNP) | VAF 145/618 reads (23%) | called by muse, mutect2, varscan2
- IGHV4-28 | c.297C>T p.S99= | Silent (SNP) | VAF 254/584 reads (43%) | called by muse, varscan2
- IGSF11 | c.1041C>T p.F347= (on ENST00000393775 / NM_001015887.3; = p.F346= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as COSV100678017; called by muse, varscan2
- IKZF1 | c.123G>T p.S41= | Silent (SNP) | VAF 126/442 reads (29%) | catalogued as rs373934387; called by muse, varscan2
- INSIG1 | c.597C>T p.G199= | Silent (SNP) | VAF 205/427 reads (48%) | catalogued as rs566604081; called by muse, varscan2
- IQCN | c.2679G>A p.R893= | Silent (SNP) | VAF 159/569 reads (28%) | called by muse, mutect2, varscan2
- ISM1 | c.1065G>A p.K355= | Silent (SNP) | VAF 137/432 reads (32%) | called by muse, mutect2, varscan2
- ITGA7 | c.3462G>A p.E1154= (on ENST00000555728; = p.E1110= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 186/552 reads (34%) | catalogued as rs370402936; called by muse, varscan2
- ITSN2 | c.4845G>A p.K1615= | Silent (SNP) | VAF 100/326 reads (31%) | catalogued as rs1195046264; called by muse, mutect2, varscan2
- JPH2 | c.1968G>A p.K656= | Silent (SNP) | VAF 126/427 reads (30%) | catalogued as COSV65902208; called by muse, mutect2, varscan2
- KCNE1 | c.246C>T p.I82= | Silent (SNP) | VAF 149/524 reads (28%) | catalogued as rs555086287, COSV61606520; called by muse, mutect2, varscan2
- KLHDC7A | c.1503C>T p.P501= | Silent (SNP) | VAF 347/571 reads (61%) | called by muse, mutect2, varscan2
- KRT1 | c.72C>T p.I24= | Silent (SNP) | VAF 129/365 reads (35%) | called by muse, mutect2, varscan2
- KRT73 | c.165G>A p.R55= | Silent (SNP) | VAF 152/504 reads (30%) | catalogued as rs1252751452, COSV59839851; called by muse, mutect2, varscan2
- KRTAP9-1 | c.441C>A p.T147= | Silent (SNP) | VAF 105/423 reads (25%) | called by muse, mutect2, varscan2
- KRTAP9-9 | c.252C>T p.I84= | Silent (SNP) | VAF 190/652 reads (29%) | catalogued as rs995744021; called by muse, varscan2
- LAP3 | c.810C>T p.P270= | Silent (SNP) | VAF 105/356 reads (29%) | called by muse, mutect2, varscan2
- LCE5A | c.153C>T p.C51= | Silent (SNP) | VAF 143/704 reads (20%) | called by muse, mutect2, varscan2
- LGR5 | c.672C>T p.S224= | Silent (SNP) | VAF 75/263 reads (29%) | catalogued as COSV57010119; called by muse, mutect2, varscan2
- LMF1 | c.57G>A p.K19= | Silent (SNP) | VAF 154/478 reads (32%) | catalogued as rs774113284, COSV51902367; called by muse, mutect2, varscan2
- LOXHD1 | c.4824C>T p.V1608= | Silent (SNP) | VAF 111/420 reads (26%) | catalogued as rs114557260; called by muse, mutect2, varscan2
- LRRC17 | c.840C>T p.I280= | Silent (SNP) | VAF 77/345 reads (22%) | called by muse, mutect2, varscan2
- LRRC32 | c.1455C>T p.A485= | Silent (SNP) | VAF 160/511 reads (31%) | catalogued as rs770680359; called by muse, mutect2, varscan2
- MAP3K9 | c.2760C>A p.A920= (on ENST00000554752 / NM_001284230.1; = p.A934= on NM_033141.4) | Silent (SNP) | VAF 234/581 reads (40%) | called by muse, mutect2, varscan2
- MCOLN1 | c.843C>T p.I281= | Silent (SNP) | VAF 236/472 reads (50%) | called by muse, mutect2, varscan2
- MEPCE | c.591G>A p.L197= | Silent (SNP) | VAF 131/502 reads (26%) | catalogued as rs1458667699, COSV52768990; called by muse, mutect2, varscan2
- MFSD4A | c.456T>G p.G152= | Silent (SNP) | VAF 102/374 reads (27%) | called by muse, mutect2, varscan2
- MGAM2 | c.2745C>T p.N915= | Silent (SNP) | VAF 203/463 reads (44%) | called by muse, mutect2, varscan2
- MROH2A | c.1188G>A p.E396= | Silent (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- MSI1 | c.921C>T p.F307= | Silent (SNP) | VAF 117/441 reads (27%) | called by muse, varscan2
- MTCH1 | c.249T>C p.A83= | Silent (SNP) | VAF 172/597 reads (29%) | called by muse, mutect2, varscan2
- MX2 | c.1407C>T p.T469= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- MYH1 | c.4944G>A p.R1648= | Silent (SNP) | VAF 72/267 reads (27%) | catalogued as COSV56844380; called by muse, mutect2, varscan2
- MYO18B | c.6759C>T p.F2253= | Silent (SNP) | VAF 125/438 reads (29%) | catalogued as rs756859848, COSV59125346; called by muse, mutect2, varscan2
- MYOCD | c.1467C>T p.V489= | Silent (SNP) | VAF 123/436 reads (28%) | called by muse, varscan2
- NIBAN2 | c.414C>T p.S138= | Silent (SNP) | VAF 99/278 reads (36%) | called by muse, mutect2, varscan2
- NOTCH1 | c.7539C>T p.S2513= | Silent (SNP) | VAF 146/423 reads (35%) | catalogued as rs758931699, COSV53038343; ClinVar: likely benign; called by mutect2, varscan2
- NR4A3 | c.1860C>T p.F620= | Silent (SNP) | VAF 74/216 reads (34%) | called by muse, mutect2, varscan2
- NSFL1C | c.1095C>T p.I365= | Silent (SNP) | VAF 76/292 reads (26%) | catalogued as rs1294982535, COSV53794088; called by muse, mutect2, varscan2
- OR10J4 | c.141G>A p.L47= | Silent (SNP) | VAF 78/427 reads (18%) | called by muse, mutect2, varscan2
- OR13C9 | c.654C>T p.Y218= | Silent (SNP) | VAF 114/406 reads (28%) | called by muse, mutect2, varscan2
- OR2W1 | c.901C>T p.L301= | Silent (SNP) | VAF 86/445 reads (19%) | called by muse, mutect2, varscan2
- OR4E1 | c.897G>A p.K299= | Silent (SNP) | VAF 56/226 reads (25%) | catalogued as rs912797306; called by muse, mutect2, varscan2
- OR4F17 | c.909A>G p.V303= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1188754568; called by mutect2, varscan2
- OR4M1 | c.183C>T p.F61= | Silent (SNP) | VAF 101/739 reads (14%) | catalogued as COSV60060150; called by muse, mutect2, varscan2
- OR52N4 | c.435G>A p.K145= | Silent (SNP) | VAF 121/408 reads (30%) | catalogued as COSV57890652; called by muse, mutect2, varscan2
- OR5D18 | c.615C>T p.T205= | Silent (SNP) | VAF 84/235 reads (36%) | called by muse, mutect2, varscan2
- OR5R1 | c.592C>T p.L198= | Silent (SNP) | VAF 135/416 reads (32%) | catalogued as COSV56573969; called by muse, mutect2, varscan2
- OR6K2 | c.891A>G p.E297= | Silent (SNP) | VAF 86/347 reads (25%) | called by muse, mutect2, varscan2
- OR6N2 | c.468C>T p.P156= | Silent (SNP) | VAF 240/486 reads (49%) | called by muse, mutect2, varscan2
- OTOG | c.1179G>A p.A393= | Silent (SNP) | VAF 103/326 reads (32%) | catalogued as rs897339453; called by muse, mutect2, varscan2
- P4HA3 | c.303G>A p.R101= | Silent (SNP) | VAF 97/334 reads (29%) | catalogued as COSV59041937; called by muse, mutect2, varscan2
- PCDHA1 | c.258G>A p.V86= | Silent (SNP) | VAF 123/441 reads (28%) | catalogued as COSV65376133; called by muse, mutect2, varscan2
- PCDHAC1 | c.1026C>T p.F342= | Silent (SNP) | VAF 130/422 reads (31%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1710C>T p.I570= | Silent (SNP) | VAF 75/209 reads (36%) | called by muse, mutect2, varscan2
- PITPNM1 | c.1998C>T p.A666= | Silent (SNP) | VAF 156/504 reads (31%) | called by muse, mutect2, varscan2
- PITPNM1 | c.834C>T p.A278= | Silent (SNP) | VAF 184/589 reads (31%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3606G>A p.R1202= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as COSV65745078; called by muse, mutect2, varscan2
- PKNOX1 | c.366C>T p.I122= | Silent (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- PLCB4 | c.2493C>T p.I831= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as rs748785049, COSV53801217; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHG2 | c.2673C>T p.V891= | Silent (SNP) | VAF 139/392 reads (35%) | called by muse, mutect2, varscan2
- PLEKHM3 | c.27C>T p.I9= | Silent (SNP) | VAF 73/224 reads (33%) | called by muse, mutect2, varscan2
- PLPPR3 | c.2025G>A p.G675= (on ENST00000520876 / NM_001270366.2; = p.G703= on NM_024888.2) | Silent (SNP) | VAF 264/524 reads (50%) | called by muse, varscan2
- PPP6R1 | c.918C>T p.A306= | Silent (SNP) | VAF 160/508 reads (31%) | catalogued as rs1175487957; called by muse, mutect2, varscan2
- PTPN5 | c.165G>A p.E55= | Silent (SNP) | VAF 155/490 reads (32%) | catalogued as rs1340178093; called by muse, mutect2, varscan2
- PTPRM | c.3984C>T p.F1328= | Silent (SNP) | VAF 76/244 reads (31%) | catalogued as rs146073268; called by muse, mutect2, varscan2
- RAET1L | c.93C>T p.H31= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- RASGRP1 | c.624G>A p.E208= | Silent (SNP) | VAF 116/371 reads (31%) | called by muse, mutect2, varscan2
- RCC1L | c.855T>C p.V285= | Silent (SNP) | VAF 110/529 reads (21%) | catalogued as rs1554444229; called by muse, mutect2, varscan2
- RFPL4A | c.675G>A p.R225= | Silent (SNP) | VAF 87/1019 reads (9%) | catalogued as rs1475626162, COSV70455009; called by muse, mutect2
- RFPL4AL1 | c.675G>A p.R225= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV59112224; called by muse, mutect2
- RHOF | c.195G>A p.K65= | Silent (SNP) | VAF 106/381 reads (28%) | called by muse, varscan2
- RIMS2 | c.3621C>T p.P1207= | Silent (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- RNF40 | c.327C>T p.L109= | Silent (SNP) | VAF 128/383 reads (33%) | catalogued as COSV100222391; called by muse, mutect2, varscan2
- RP1 | c.2988G>A p.G996= | Silent (SNP) | VAF 85/296 reads (29%) | catalogued as rs1360812415; called by muse, mutect2, varscan2
- RUNX1T1 | c.1785C>T p.T595= (on ENST00000265814 / NM_001198628.1; = p.T568= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/362 reads (34%) | called by muse, mutect2, varscan2
- SALL4 | c.2466G>A p.R822= | Silent (SNP) | VAF 71/221 reads (32%) | catalogued as COSV53854954; called by muse, mutect2, varscan2
- SATB1 | c.2130C>T p.S710= | Silent (SNP) | VAF 134/406 reads (33%) | catalogued as rs761441678, COSV100113256; called by muse, mutect2, varscan2
- SCAF1 | c.3015C>T p.S1005= | Silent (SNP) | VAF 150/488 reads (31%) | catalogued as rs955056109; called by muse, varscan2
- SCN11A | c.2382C>T p.I794= | Silent (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.633C>T p.H211= | Silent (SNP) | VAF 140/442 reads (32%) | catalogued as rs372247265; called by muse, mutect2, varscan2
- SKOR2 | c.408G>A p.P136= | Silent (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- SLC25A20 | c.231C>T p.A77= | Silent (SNP) | VAF 78/250 reads (31%) | catalogued as rs1028268779; called by muse, mutect2, varscan2
- SLC7A9 | c.453G>A p.V151= | Silent (SNP) | VAF 96/326 reads (29%) | catalogued as COSV50095148; called by muse, varscan2
- SLCO1C1 | c.849C>T p.I283= | Silent (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.756C>T p.T252= | Silent (SNP) | VAF 81/322 reads (25%) | called by muse, mutect2, varscan2
- SNCAIP | c.2745G>A p.K915= | Silent (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- SORCS3 | c.3354C>T p.S1118= | Silent (SNP) | VAF 96/301 reads (32%) | catalogued as rs763369492; called by muse, varscan2
- SPATA7 | c.537C>T p.S179= | Silent (SNP) | VAF 199/452 reads (44%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2760G>A p.K920= (on ENST00000621492; = p.K886= on NM_025248.3) | Silent (SNP) | VAF 85/365 reads (23%) | catalogued as rs746642772; called by muse, mutect2, varscan2
- STAB2 | c.2766C>T p.C922= | Silent (SNP) | VAF 77/341 reads (23%) | called by muse, mutect2, varscan2
- STK10 | c.912G>A p.R304= | Silent (SNP) | VAF 115/380 reads (30%) | called by muse, mutect2, varscan2
- TARM1 | c.234G>A p.P78= (on ENST00000616041 / NM_001330650.1; = p.P70= on NM_001135686.3) | Silent (SNP) | VAF 154/555 reads (28%) | catalogued as rs776141965; called by muse, mutect2, varscan2
- TARS2 | c.972C>T p.F324= | Silent (SNP) | VAF 171/373 reads (46%) | catalogued as rs139427355; called by muse, mutect2, varscan2
- TAS1R2 | c.1671C>T p.V557= | Silent (SNP) | VAF 226/380 reads (59%) | called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 144/428 reads (34%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, varscan2
- TENM2 | c.1548G>A p.E516= (on ENST00000518659 / NM_001122679.2; = p.E284= on NM_001080428.3) | Silent (SNP) | VAF 103/313 reads (33%) | catalogued as rs1007666132, COSV69130882; called by muse, mutect2, varscan2
- TEX33 | c.405G>A p.T135= (on ENST00000381821 / NM_001163857.2; = p.T50= on NM_178552.4) | Silent (SNP) | VAF 123/405 reads (30%) | catalogued as rs774433566, COSV67822014; called by muse, mutect2, varscan2
- TEX48 | c.336C>T p.F112= | Silent (SNP) | VAF 70/212 reads (33%) | called by muse, mutect2, varscan2
- TFR2 | c.1029C>T p.F343= | Silent (SNP) | VAF 111/559 reads (20%) | called by muse, mutect2, varscan2
- TLE1 | c.1986C>A p.S662= | Silent (SNP) | VAF 70/268 reads (26%) | called by muse, mutect2, varscan2
- TLNRD1 | c.597C>T p.A199= | Silent (SNP) | VAF 269/537 reads (50%) | catalogued as rs1196995882; called by muse, mutect2, varscan2
- TM9SF4 | c.1614C>T p.F538= | Silent (SNP) | VAF 105/310 reads (34%) | catalogued as COSV54106254; called by muse, mutect2, varscan2
- TMC2 | c.252G>A p.G84= | Silent (SNP) | VAF 202/619 reads (33%) | catalogued as COSV62651077; called by muse, mutect2, varscan2
- TMEM150C | c.483G>A p.R161= | Silent (SNP) | VAF 96/294 reads (33%) | called by muse, mutect2, varscan2
- TMEM187 | c.327C>T p.R109= | Silent (SNP) | VAF 186/300 reads (62%) | called by muse, mutect2, varscan2
- TMEM87B | c.1329C>T p.I443= | Silent (SNP) | VAF 88/294 reads (30%) | called by muse, mutect2, varscan2
- TNN | c.3282G>A p.R1094= | Silent (SNP) | VAF 251/542 reads (46%) | called by muse, mutect2, varscan2
- TREM1 | c.693C>T p.F231= | Silent (SNP) | VAF 142/386 reads (37%) | called by muse, mutect2, varscan2
- TRIM16 | c.1515C>T p.I505= | Silent (SNP) | VAF 127/430 reads (30%) | catalogued as COSV60887279; called by muse, mutect2, varscan2
- TRIM50 | c.1098C>T p.I366= | Silent (SNP) | VAF 123/586 reads (21%) | catalogued as COSV53091780; called by muse, mutect2, varscan2
- TRIM50 | c.918C>T p.L306= | Silent (SNP) | VAF 248/520 reads (48%) | called by muse, mutect2, varscan2
- TRIM60 | c.54C>T p.I18= | Silent (SNP) | VAF 80/252 reads (32%) | called by muse, varscan2
- TTN | c.43227C>T p.V14409= (on ENST00000591111; = p.V6985= on NM_003319.4) | Silent (SNP) | VAF 56/214 reads (26%) | catalogued as rs1383775947; called by muse, mutect2, varscan2
- TTN | c.22938G>A p.V7646= (on ENST00000591111; = p.V6719= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 106/327 reads (32%) | catalogued as rs867356601; called by muse, mutect2, varscan2
- TTN | c.639C>T p.I213= | Silent (SNP) | VAF 75/272 reads (28%) | called by muse, mutect2, varscan2
- TUBAL3 | c.168C>T p.F56= | Silent (SNP) | VAF 91/338 reads (27%) | catalogued as rs534913397, COSV66814761; called by muse, mutect2, varscan2
- UBAC2 | c.639C>T p.F213= (on ENST00000403766 / NM_001144072.2; = p.F178= on NM_177967.4) | Silent (SNP) | VAF 112/338 reads (33%) | called by muse, mutect2, varscan2
- UROC1 | c.588C>T p.A196= | Silent (SNP) | VAF 81/265 reads (31%) | called by muse, mutect2, varscan2
- USH2A | c.1437C>T p.F479= | Silent (SNP) | VAF 76/395 reads (19%) | catalogued as rs780470999, COSV56326187; called by muse, mutect2, varscan2
- USP17L2 | c.780G>A p.R260= | Silent (SNP) | VAF 111/666 reads (17%) | called by muse, varscan2
- VSIG4 | c.1017C>T p.F339= | Silent (SNP) | VAF 164/255 reads (64%) | catalogued as rs773581890, COSV101038104; called by muse, mutect2, varscan2
- VWA3B | c.3231C>T p.S1077= | Silent (SNP) | VAF 112/347 reads (32%) | called by muse, mutect2, varscan2
- VWA8 | c.3960G>A p.G1320= | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- WDFY4 | c.8910G>A p.R2970= | Silent (SNP) | VAF 123/329 reads (37%) | called by muse, varscan2
- ZBED4 | c.2259C>T p.F753= | Silent (SNP) | VAF 122/367 reads (33%) | catalogued as rs369682264; called by muse, mutect2, varscan2
- ZBED9 | c.3486C>T p.I1162= | Silent (SNP) | VAF 50/266 reads (19%) | called by muse, varscan2
- ZDHHC3 | c.27C>T p.F9= | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as COSV56100811; called by muse, mutect2, varscan2
- ZER1 | c.1626G>A p.Q542= | Silent (SNP) | VAF 61/270 reads (23%) | catalogued as rs1481028986; called by muse, mutect2, varscan2
- ZER1 | c.858C>T p.I286= | Silent (SNP) | VAF 117/365 reads (32%) | catalogued as COSV99401986; called by muse, mutect2, varscan2
- ZFP36 | c.756C>T p.T252= (on ENST00000594442; = p.T246= on NM_003407.5) | Silent (SNP) | VAF 179/483 reads (37%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1731G>A p.Q577= | Silent (SNP) | VAF 116/405 reads (29%) | catalogued as rs764622920; called by muse, mutect2, varscan2
- ZNF215 | c.1074G>A p.G358= | Silent (SNP) | VAF 66/219 reads (30%) | called by muse, mutect2, varscan2
- ZNF487 | c.621G>T p.L207= | Silent (SNP) | VAF 56/199 reads (28%) | called by muse, varscan2
- ZNF773 | c.1032C>T p.S344= | Silent (SNP) | VAF 137/442 reads (31%) | catalogued as rs1282600003; called by muse, mutect2, varscan2
- ZNF781 | c.414C>T p.F138= | Silent (SNP) | VAF 107/329 reads (33%) | catalogued as COSV62202279; called by muse, mutect2, varscan2
- ZSCAN5C | c.600C>T p.F200= | Silent (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2
- AC002519.1 | chr16:31792701 C>T | 3'Flank (SNP) | VAF 92/281 reads (33%) | catalogued as rs1227825593; called by muse, mutect2, varscan2
- ADI1 | c.121-881C>T | Intron (SNP) | VAF 71/216 reads (33%) | called by muse, mutect2, varscan2
- AGXT2 | chr5:35049402 G>A | 5'Flank (SNP) | VAF 77/232 reads (33%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.727-3310G>A | Intron (SNP) | VAF 74/293 reads (25%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27574235 C>T | 5'Flank (SNP) | VAF 67/267 reads (25%) | called by muse, mutect2, varscan2
- CCDC158 | c.1029+3614T>A | Intron (SNP) | VAF 74/227 reads (33%) | called by muse, mutect2, varscan2
- CHN1 | c.627+499C>T | Intron (SNP) | VAF 82/265 reads (31%) | catalogued as rs773666187; called by muse, mutect2, varscan2
- CPLANE1 | c.*5636C>T | 3'UTR (SNP) | VAF 102/333 reads (31%) | catalogued as rs1454889932, COSV57058563; called by muse, mutect2, varscan2
- DCHS2 | n.4006T>G | RNA (SNP) | VAF 58/185 reads (31%) | called by muse, mutect2, varscan2
- DENND10 | c.-1G>A | 5'UTR (SNP) | VAF 92/303 reads (30%) | called by muse, varscan2
- DLG2 | c.205-65586G>A | Intron (SNP) | VAF 120/384 reads (31%) | catalogued as COSV99712835; called by muse, mutect2, varscan2
- ERI3 | c.490-3060C>T | Intron (SNP) | VAF 375/522 reads (72%) | catalogued as rs1024942636; called by muse, mutect2, varscan2
- GCNT2 | c.925+27329T>G | Intron (SNP) | VAF 166/654 reads (25%) | called by muse, mutect2, varscan2
- GMPPA | c.854-43C>T | Intron (SNP) | VAF 161/479 reads (34%) | catalogued as rs755535192, COSV100354931; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-13748G>A | Intron (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2, varscan2
- LSP1 | c.54-13258C>T | Intron (SNP) | VAF 162/546 reads (30%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671020 G>A | 3'Flank (SNP) | VAF 99/397 reads (25%) | catalogued as rs765790536; called by muse, mutect2, varscan2
- MUCL3 | c.947-760C>A | Intron (SNP) | VAF 153/641 reads (24%) | called by mutect2, varscan2
- MUCL3 | c.947-429C>T | Intron (SNP) | VAF 403/797 reads (51%) | catalogued as rs1402705817; called by muse, mutect2, varscan2
- PKD1L2 | n.2863G>A | RNA (SNP) | VAF 50/211 reads (24%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2862G>A | RNA (SNP) | VAF 51/212 reads (24%) | catalogued as rs371510371; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+579C>T | Intron (SNP) | VAF 110/507 reads (22%) | called by muse, mutect2, varscan2
- PTPRQ | c.181-374C>T | Intron (SNP) | VAF 14/98 reads (14%) | called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20266G>A | Intron (SNP) | VAF 27/85 reads (32%) | catalogued as COSV67443683; called by muse, mutect2, varscan2
- SPTBN1 | c.6420+71C>T | Intron (SNP) | VAF 58/272 reads (21%) | catalogued as rs267599411; called by muse, mutect2
- SUCO | chr1:172532484 C>T | 5'Flank (SNP) | VAF 69/319 reads (22%) | catalogued as rs1009606390, COSV99743854; called by muse, mutect2, varscan2
- USH1C | c.1284+1146C>T | Intron (SNP) | VAF 86/283 reads (30%) | called by muse, mutect2, varscan2
- Y_RNA | chr8:38745470 G>T | 3'Flank (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
